Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040037-09A.4 (aliquot TARGET-15-SJMPAL040037-09A.4-01D) from TARGET case TARGET-15-SJMPAL040037, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,594 days).
Specimen TARGET-15-SJMPAL040037-09A.4: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b1b37b3-a1ac-4e86-8fc8-7dbe6eaf1e79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040037-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040037-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/996c98d2-22a9-42db-b7ef-8cfd782f24be

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Ins 2, Intron 1, 3'UTR 1, RNA 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OSGIN1 | n.1028+1G>A | Splice Site (SNP) | VAF 17/49 reads (35%) | catalogued as rs768497100; called by muse, mutect2, varscan2
- SSC5D | c.3854C>T p.T1285M | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs201172616; called by muse, mutect2, varscan2
- TBX3 | c.1196C>T p.T399M (on ENST00000257566 / NM_016569.4; = p.T379M on NM_005996.4) | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs746953122; called by muse, mutect2, varscan2
- WT1 | c.1189delinsAGATCA p.Q397Rfs*42 | Frame Shift Ins (INS) | VAF 60/190 reads (32%) | catalogued as CM041869, COSV60066810, COSV60071867; called by pindel, varscan2*
- WT1 | c.1102_1103insTGGGGCG p.R368Lfs*7 | Frame Shift Ins (INS) | VAF 90/270 reads (33%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by pindel, varscan2
- B3GNT6 | c.644C>A p.A215E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CAMTA1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX17 | c.795T>A p.D265E | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IRF5 | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC21 | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 156/450 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- WWC3 | c.1267C>A p.R423= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV66502079; called by muse, mutect2
- ARHGEF4 | c.428-16116G>A | Intron (SNP) | VAF 115/267 reads (43%) | called by muse, mutect2, varscan2
- FAM205BP | n.821G>A | RNA (SNP) | VAF 13/129 reads (10%) | catalogued as rs369553984; called by muse, mutect2
- OGG1 | c.*7G>A | 3'UTR (SNP) | VAF 87/208 reads (42%) | called by muse, mutect2, varscan2
